TCGA case TCGA-EY-A1GK — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/972db411-9744-46f0-89c7-efe14135f1b4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 74.3 years (27,127 days); Year of diagnosis: 2009; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 693 days (1.9 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 12.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 58.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Days to treatment start: 107 days; Days to treatment end: 121 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Prior malignancy of the ureter (histology not recorded by GDC). Laterality: Left.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 504 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 693 days (1.9 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 160 cm; BMI: 41.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EY-A1GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-EY-A1GK-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 30.
- Sample TCGA-EY-A1GK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EY-A1GK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Radiation treatment: Radiation type other: HDR Brachytherapy.
- Other malignancy form: Malignancy type: Prior Malignancy.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1009.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a previous cancer of the ureter. No systemic radiation or chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 693 days; disease-specific survival: no event (censored), 693 days; disease-free interval: no event (censored), 693 days; progression-free interval: no event (censored), 693 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EY-A1GK-01A-11D-A13J-01): tumor purity 0.7, ploidy 2.04, whole-genome doublings 0.
